Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042787-09A.1 (aliquot TARGET-15-SJMPAL042787-09A.1-01D) from TARGET case TARGET-15-SJMPAL042787, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,941 days).
Specimen TARGET-15-SJMPAL042787-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f7b98c5-1505-48ea-9e49-823aa8c3300d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042787-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042787-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cb8584a-962a-44d6-9923-d8f57b0b348f

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Splice Region 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by muse, mutect2, varscan2
- ABCC10 | c.2130C>A p.I710= (on ENST00000372530 / NM_001198934.2; = p.I682= on NM_033450.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 4/32 reads (13%) | catalogued as rs1193341363; called by muse, mutect2
- FOXN4 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1030853041; called by muse, mutect2, varscan2
- FRMPD4 | c.3593G>A p.R1198Q | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs376320353, COSV66212003; called by muse, mutect2, varscan2
- JPH2 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs766295044, COSV65902954; called by muse, mutect2, varscan2
- MSRA | c.336A>T p.K112N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1234527523, COSV57798715; called by muse, mutect2, varscan2
- MYF6 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV57350563; called by muse, mutect2, varscan2
- NCAM2 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs937689487, COSV99034556; called by muse, mutect2, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, varscan2
- STXBP5L | c.2126G>A p.R709H | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs201266367; called by muse, mutect2, varscan2
- IQGAP2 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2
- ITGA1 | c.1084C>A p.L362M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RRAGA | c.515C>A p.A172D | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TNRC18 | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.515); called by muse, mutect2
- USP9X | c.5985_5986insCCT p.N1995_V1996insP | In Frame Ins (INS) | VAF 28/85 reads (33%) | called by mutect2, pindel, varscan2
- PHC1 | c.786C>A p.L262= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.963G>A p.T321= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as rs553573836; called by muse, varscan2
- XRN1 | c.1638A>C p.P546= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- ELP3 | c.1568-6438C>A | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
